CCDI case PBBXUY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7e1b79c8-6bf0-42cd-b48b-f77290761a80

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Desmoplastic infantile astrocytoma: ICD-O-3 morphology code: 9412/1; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 0.9 years (344 days).

Biospecimens (3 samples)
- Sample 0DK5H5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK5HK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DK5HQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
